CPTAC case C3N-04277 — Larynx — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Larynx. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7120a122-bc2f-4c2e-bbf5-b1059b898d28

Demographics
Sex at birth: male; Race: white; Year of birth: 1945; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Larynx, NOS; Site of resection or biopsy: Larynx, NOS; Age at diagnosis: 72.4 years (26,445 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,923 days (5.3 years); Progression or recurrence: no; Days to last follow up: 1,923 days (5.3 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 1 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 5; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.

Follow-up (6 entries)
- Days to follow up: 436 days (1.2 years); Disease response: Tumor Free; Karnofsky performance status: 60; ECOG performance status: 3.
- Days to follow up: 762 days (2.1 years); Disease response: Tumor Free; Karnofsky performance status: 60; ECOG performance status: 2.
- Days to follow up: 1,162 days (3.2 years); Disease response: Tumor Free; Karnofsky performance status: 60; ECOG performance status: 2.
- Days to follow up: 1,162 days (3.2 years); Disease response: Complete Response; Karnofsky performance status: 60; ECOG performance status: 2.
- Days to follow up: 1,508 days (4.1 years); Disease response: Tumor Free; Karnofsky performance status: 60; ECOG performance status: 2.
- Days to follow up: 1,923 days (5.3 years); Disease response: Tumor Free; Karnofsky performance status: 60; ECOG performance status: 2.

Other clinical attributes
- Weight: 71 kg; Height: 165 cm; BMI: 26.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 23.5; Cigarettes per day: 10; Tobacco smoking onset year: 1970; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 52.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-04277-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 131 mg; Time between excision and freezing: 12 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-04277-22: Section location: Larynx; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3N-04277-04: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 126 mg; Time between excision and freezing: 12 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-04277-12: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Time between excision and freezing: 12 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-04277-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 1 day; Method of sample procurement: Blood Draw.
